Surgical pathology report (de-identified scan), TCGA case TCGA-HF-7133, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-7133-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details

Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments
---------------	-------------	--------------------	----------------	-------------------------	---------------------------	--------------------------------	-----------------

	TUMOUR	FF	Stomach	GAST			
--	--------	----	---------	------	--	--	--

	BUFFY	FF		GAST			
--	-------	----	--	------	--	--	--

[page 2 of 3]
Histology and staging

Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differenti ation	Pathologic al T
------------------------------	----------------------	----------------------	-----------------------------------	---------------------	-----------	-------------------------------	--------------------

█	█	RESECT	Stomach	17	Adenocarcinoma, mucinous	II	T2b
---	---	--------	---------	----	--------------------------	----	-----

█	█	RESECT	Stomach	17	Adenocarcinoma, mucinous	II	T2b
---	---	--------	---------	----	--------------------------	----	-----

[page 3 of 3]
Pathologic al N	Clinical M	Histology Comments	Slide URL
		Macroscopic tumour configuration: type I (protruded), Borrmann type I (polypoid, exophytic). Multiple nodules of the tumour are seen within the perigastric fat.	
N3	M0	Macroscopic tumour configuration: type I (protruded), Borrmann type I (polypoid, exophytic). Multiple nodules of the tumour are seen within the perigastric fat.	
N3	M0		

Source: NCI Genomic Data Commons file 72781674-76f7-4139-ab82-37475c870b38 (TCGA-HF-7133.1706DDDB-E700-4CBE-ACCA-A9F23BD82442.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).